Somatic mutation profile of tumor specimen ER-AE8R-TTM1-A (aliquot ER-AE8R-TTM1-A-1-0-D-A595-35) from EXCEPTIONAL_RESPONDERS case ER-AE8R, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell carcinoma; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 49.4 years (18,031 days).
Specimen ER-AE8R-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cd7754e-f434-4027-bb00-afa0a4f16468.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AE8R-NT1-A (Solid Tissue Normal), aliquot ER-AE8R-NT1-A-1-0-D-A595-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5a50d3f-8e67-4e4b-a7a2-aa7c39f7134b

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 48/521 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56243970; called by muse, mutect2
- BRCA2 | c.5188A>T p.N1730Y | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs397507770, CM010168; ClinVar: not provided; called by muse, mutect2
- CDKN2A | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 60/444 reads (14%) | catalogued as CM127042, COSV58683179, COSV58691985, COSV58722986; called by muse, mutect2, varscan2
- FGF14 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 60/497 reads (12%) | catalogued as COSV101086782; called by muse, mutect2, varscan2
- CREBBP | c.6221T>C p.L2074P | Missense Mutation (SNP) | VAF 59/478 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
